Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6923, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6923-01A (Primary Tumor).

Department of Cancer Pathology (cito)

copy No. 2

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **Multiple organ resection – segment of the large intestine**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the sigmoid colon**

Examination performed on:

Macroscopic description:

A 12 cm length of the large intestine with fat tissue sized 14 x 6 x 9.5 cm. Tumour sized 4 x 3 x 1.5 cm detected in the mucosa. The lesion surrounding 50% of the intestine circumference, removed by 5 cm from one of the incision lines, and 5.3 from the opposite one. The lesion infiltrates macroscopically the muscular membrane. Diverticulum 1 cm in diameter found outside the tumour.

Microscopic description:

Adenocarcinoma tubulopapillare (G2). Infiltratio carcinomatosa profunda tunicae muscularis propriae . Incision lines free of neoplastic lesions. Lymphonodulitis reactiva (No XI).

Histopathological Diagnosis:

Adenocarcinoma tubulopapillare coli. Tubulopapillar adenocarcinoma of the colon. (G2, Dukes B, Astler - Coller BI, pT2, pNO).

Compliance validated by:

CONTACT YOU DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 2cbf41f0-d4ac-4e4d-9b7b-53ffa6609da4 (TCGA-D5-6923.3523F7AC-0A52-44CB-9B99-068955CCB1DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).